Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A6S6, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A6S6-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology

Update Date/Time:
Final 1

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

C6CF ICD-O-3
Oligoastrocytoma, grade III
9382/3
path
Oligoastrocytoma 9382/3
Site 4 Brain, supratentorial NOS
C71.0
JW 7/24/13

Surgical Pathology Report

Patient Name: Accession #:
Med: Rec.: Phone Number:
DOB: (Age:) Gender: F
Client:
Taken:
Received:
Reported:
Physician(s):
Phy Location:

CLINICAL HISTORY

year-old woman with right frontal image abnormality
has headaches and possibly glioma, non-enhancing.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, Right frontal biopsy

B: Brain, Right frontal lobe tumor biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right frontal, excision:

1. Mixed oligoastrocytoma, diffusely infiltrating, with atypical features.

2. MIB-1 proliferation index: \R\ 4%.

See Comment.

COMMENT

In both specimens, a moderately cellular glial neoplasm diffusely infiltrates the cerebral cortex and white matter. The neoplastic cells are naked, mostly round, but also elongated (mainly in the white matter), with slight pleomorphism. Focally, there are hypercellular areas ("proliferation centers"), perinuclear halos, and one zone of microcystic change. Mitotic figures are found with difficulty, and the MIB-1 proliferation index is at about 4% in the more active areas. There is no microvascular cellular proliferation or necrosis.

The neoplasm is a mixed oligoastrocytoma, predominantly oligodendrocytic. There are no overt features of anaplasia (microvascular proliferation or necrosis). There are, however, proliferation centers and a few mitoses that probably portend an aggressive behavior, i. e. an "intermediate" mixed glioma.

Electronically Signed Out

Senior Staff Pathologist

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled (B2).

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the

as

[page 2 of 2]
required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

Consultant:

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, Right frontal biopsy, touch prep and smears: Glioma. Infiltrative.

Senior Staff Pathologist

GROSS DESCRIPTION

A.
Received fresh, one fragment, 0.6 x 0.25-cm. Semi firm, grayish-white. In total, A1.
B.
SPECIMEN: Right frontal lobe tumor.
FIXATIVE: Formalin.
GENERAL: A 4.5 x 3.5 x 1.3 cm. aggregate of four irregularly shaped gray-tan fragments of brain tissue. Larger fragments are sectioned.
SECTIONS: B1-B5 all submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates rather sparse glial fibrillogenesis by the neoplastic cells, focally resembling like gliofibrillary oligodendrocytes. About 20% of the neoplastic cells over express the p53 protein. With the MIB-1 there is a proliferation index of about 4% in the more active areas.

ICD-9(s):

191.1 191.1

Billing Fee Code(s):

Histo Data

Part A: Brain, Right frontal biopsy
Taken: Received:
Stain/cnt Block Ordered Comment
H/E x 1 1
Part B: Brain, Right frontal lobe tumor biopsy
Taken: Received:
Stain/cnt Block Ordered Comment
H/E x 1 1
mGFAP-DA x 1 2
H/E x 1 2
MGMT x 1 2
MIB1-DA x 1 2
P53DO7 x 1 2
H/E x 1 3
H/E x 1 4
H/E x 1 5
MIB1-DA x 1 5
*** End of Report ***

Source: NCI Genomic Data Commons file d5f87aab-f207-47fe-b10d-af568ba87605 (TCGA-DU-A6S6.0F38FC8D-1080-4D25-9D40-644B5795F308.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).